Somatic mutation profile of tumor specimen MMRF_1643_1_BM_CD138pos (aliquot MMRF_1643_1_BM_CD138pos_T1_KBS5U_L04312) from MMRF case MMRF_1643, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 62.4 years (22,787 days).
Specimen MMRF_1643_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 36affbe4-fcbb-49ae-bf2a-64abb26cce65.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1643_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1643_1_PB_Whole_C3_KBS5U_L04323; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a660053d-9851-46b7-b5b1-d88fdadc9869

The open-access MAF lists 133 somatic variants for this specimen: 56 protein-altering or splice-affecting, 19 silent, 58 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, 3'UTR 30, Silent 19, Intron 11, 5'UTR 9, 3'Flank 4, 5'Flank 3, Nonsense Mutation 2, Splice Site 2, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DIS3 | c.2339G>A p.R780K | Missense Mutation (SNP) | VAF 27/91 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66705570, COSV66707409; called by muse, mutect2, varscan2
- LHCGR | c.1660C>T p.R554* | Nonsense Mutation (SNP) | VAF 142/312 reads (46%) | catalogued as rs121912524, CM960940, COSV54292419; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AADACL4 | c.311C>T p.P104L | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs753850598, COSV66106997; called by muse, mutect2, varscan2
- ASMT | c.169G>A p.A57T | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs1252610037; called by muse, mutect2, varscan2
- C19orf84 | c.319G>A p.G107R | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.219); catalogued as rs780890812; called by muse, mutect2, varscan2
- CEMIP | c.1800C>G p.I600M | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.131); catalogued as COSV54992978; called by muse, mutect2, varscan2
- CFAP46 | c.6792G>T p.R2264S | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT tolerated (0.3); PolyPhen benign (0.02); catalogued as rs745445388; called by muse, mutect2, varscan2
- CHRNA7 | c.689C>T p.T230M | Missense Mutation (SNP) | VAF 49/97 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769876615, COSV60970086; called by muse, mutect2, varscan2
- CIITA | c.2998G>A p.G1000R | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760933605; called by muse, mutect2, varscan2
- CUEDC1 | c.505C>T p.R169C | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.634); catalogued as rs1310616018; called by muse, mutect2, varscan2
- DMRTB1 | c.79G>A p.A27T | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.162); catalogued as COSV65112636; called by muse, mutect2, varscan2
- EEF1A1 | c.754G>A p.D252N | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.047); catalogued as COSV58548873, COSV58549955; called by muse, mutect2, varscan2
- FAM71E2 | c.2396G>A p.R799H | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.467); catalogued as rs949548424, COSV58483534; called by muse, mutect2, varscan2
- GRIA2 | c.589C>A p.Q197K | Missense Mutation (SNP) | VAF 75/76 reads (99%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.8); catalogued as COSV52390990; called by muse, mutect2, varscan2
- IGHJ3 | c.31A>G p.M11V | Missense Mutation (SNP) | VAF 22/30 reads (73%) | PolyPhen benign (0.007); catalogued as rs185836312; called by muse, varscan2
- IGHV1-69 | c.161G>A p.S54N | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs1064564; called by muse, varscan2
- IGHV2-70 | c.148A>G p.T50A | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as rs373039668; called by muse, varscan2
- IGLL5 | c.79C>G p.L27V | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.087); catalogued as rs777349722, COSV73249535, COSV73250343, COSV73250409; called by muse, mutect2, varscan2
- IGLV3-1 | c.65A>C p.E22A | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT tolerated (0.6); PolyPhen benign (0.018); catalogued as rs528877557; called by muse, varscan2
- INAVA | c.1289C>T p.T430M | Missense Mutation (SNP) | VAF 38/73 reads (52%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as rs150140877, COSV100950054; called by muse, mutect2, varscan2
- INSL5 | c.236C>T p.A79V | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT tolerated (0.33); PolyPhen benign (0.009); catalogued as rs372109860; called by muse, mutect2, varscan2
- KIF20A | c.1429C>T p.R477C | Missense Mutation (SNP) | VAF 86/129 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs752329282; called by muse, mutect2, varscan2
- MUC16 | c.11009C>A p.A3670E | Missense Mutation (SNP) | VAF 35/254 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.451); catalogued as COSV101201753; called by muse, mutect2, varscan2
- RNF123 | c.1203+1G>A p.X401_splice | Splice Site (SNP) | VAF 45/110 reads (41%) | catalogued as rs1278938127; called by muse, mutect2, varscan2
- ROR2 | c.233C>T p.T78M | Missense Mutation (SNP) | VAF 137/211 reads (65%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.978); catalogued as rs369545969; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCN1A | c.4096G>A p.V1366I (on ENST00000303395 / NM_001202435.3; = p.V1355I on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 99/221 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121918805, CM076498, COSV57681267; ClinVar: not provided; called by muse, mutect2, varscan2
- SLC6A3 | c.1757C>A p.S586Y | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.361); catalogued as COSV54366094; called by muse, mutect2, varscan2
- SPTY2D1 | c.290A>G p.N97S | Missense Mutation (SNP) | VAF 58/321 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.314); catalogued as rs768788165; called by muse, mutect2, varscan2
- TRPC4 | c.89C>A p.S30* | Nonsense Mutation (SNP) | VAF 77/166 reads (46%) | catalogued as rs145847458; called by muse, mutect2, varscan2
- TRPM3 | c.2960G>A p.R987H (on ENST00000357533 / NM_001366142.2; = p.R830H on NM_020952.6) | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.949); catalogued as rs1432206553, COSV62586228; called by muse, mutect2
- VAT1L | c.979C>T p.R327W | Missense Mutation (SNP) | VAF 43/98 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs1055500524, COSV56825520; called by muse, mutect2, varscan2
- VPS18 | c.1177C>T p.R393W | Missense Mutation (SNP) | VAF 76/291 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs199697224, COSV55029016; called by muse, mutect2, varscan2
- ATP11C | c.269G>T p.S90I | Missense Mutation (SNP) | VAF 13/14 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BCAS4 | c.619G>A p.A207T | Missense Mutation (SNP) | VAF 82/173 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.237); called by muse, mutect2, varscan2
- CCDC190 | c.577C>A p.P193T | Missense Mutation (SNP) | VAF 53/117 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- DLGAP2 | c.2492A>G p.E831G | Missense Mutation (SNP) | VAF 37/61 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- EYS | c.5789T>C p.V1930A | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.56); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- FLVCR1 | c.1428G>T p.L476F | Missense Mutation (SNP) | VAF 43/104 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- GPCPD1 | c.1471T>A p.L491I | Missense Mutation (SNP) | VAF 44/100 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GRIK4 | c.2580C>G p.H860Q | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRIK4 | c.2581C>T p.P861S | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- IRS1 | c.217A>T p.N73Y | Missense Mutation (SNP) | VAF 53/114 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- ITGB6 | c.323G>A p.S108N | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KIF16B | c.1516G>A p.E506K | Missense Mutation (SNP) | VAF 48/101 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KLHL6 | c.54G>C p.K18N | Missense Mutation (SNP) | VAF 49/99 reads (49%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- MDN1 | c.8128T>C p.S2710P | Missense Mutation (SNP) | VAF 46/115 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MTTP | c.1342_1344+1del p.X448_splice | Splice Site (DEL) | VAF 42/102 reads (41%) | called by mutect2, pindel, varscan2
- NSMCE3 | c.316A>G p.I106V | Missense Mutation (SNP) | VAF 105/226 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- PCGF3 | c.402_405del p.N134Kfs*21 | Frame Shift Del (DEL) | VAF 16/38 reads (42%) | called by pindel, varscan2
- PCLO | c.15396C>A p.H5132Q | Missense Mutation (SNP) | VAF 150/528 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- SLC38A1 | c.1038G>T p.Q346H | Missense Mutation (SNP) | VAF 59/111 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- TACC2 | c.2360T>G p.L787W | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TFR2 | c.516G>A p.M172I | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- WDFY3 | c.7991A>G p.D2664G | Missense Mutation (SNP) | VAF 8/206 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.247); called by muse, mutect2
- ZNF142 | c.2234C>T p.P745L (on ENST00000411696 / NM_001379660.1; = p.P545L on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- ZNF536 | c.3385T>G p.S1129A | Missense Mutation (SNP) | VAF 9/149 reads (6%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); called by muse, mutect2
- AHNAK | c.90C>T p.D30= | Silent (SNP) | VAF 23/84 reads (27%) | catalogued as rs759318193; called by muse, mutect2, varscan2
- ARHGEF17 | c.1593C>T p.R531= | Silent (SNP) | VAF 62/155 reads (40%) | catalogued as rs961492906; called by muse, mutect2, varscan2
- C1QL2 | c.645C>T p.D215= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as rs371906170; called by muse, mutect2, varscan2
- C2CD2 | c.1395C>T p.S465= | Silent (SNP) | VAF 68/139 reads (49%) | catalogued as rs768612077; called by muse, mutect2, varscan2
- FAM180A | c.250C>A p.R84= | Silent (SNP) | VAF 68/110 reads (62%) | called by muse, mutect2, varscan2
- FAM184B | c.366G>A p.S122= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as rs1443605993; called by muse, mutect2, varscan2
- FZD9 | c.1461G>A p.A487= | Silent (SNP) | VAF 48/147 reads (33%) | catalogued as rs1475934670; called by muse, mutect2, varscan2
- GABRB3 | c.192G>A p.T64= | Silent (SNP) | VAF 33/176 reads (19%) | catalogued as rs370850076; called by muse, mutect2, varscan2
- GNA14 | c.96G>A p.A32= | Silent (SNP) | VAF 11/89 reads (12%) | catalogued as rs747218320; called by muse, mutect2, varscan2
- GTPBP3 | c.1371G>A p.A457= | Silent (SNP) | VAF 21/67 reads (31%) | catalogued as rs528495325; called by muse, mutect2, varscan2
- ICE2 | c.1524G>A p.L508= | Silent (SNP) | VAF 14/110 reads (13%) | catalogued as COSV55034827; called by muse, mutect2, varscan2
- IGHV1-69 | c.279A>G p.K93= | Silent (SNP) | VAF 75/83 reads (90%) | catalogued as rs11557994; called by muse, mutect2, varscan2
- IRX3 | c.333G>A p.P111= | Silent (SNP) | VAF 14/46 reads (30%) | called by muse, mutect2, varscan2
- PCLO | c.5082C>T p.D1694= | Silent (SNP) | VAF 30/157 reads (19%) | catalogued as rs367988765, COSV100436349; called by muse, mutect2, varscan2
- RAI1 | c.4032C>T p.F1344= | Silent (SNP) | VAF 41/96 reads (43%) | catalogued as rs147375487; called by muse, mutect2, varscan2
- RNF123 | c.3438T>C p.Y1146= | Silent (SNP) | VAF 28/79 reads (35%) | catalogued as rs759596527; called by muse, mutect2, varscan2
- UBN2 | c.3606A>G p.P1202= | Silent (SNP) | VAF 17/94 reads (18%) | called by muse, mutect2, varscan2
- UBQLNL | c.123G>A p.Q41= | Silent (SNP) | VAF 29/91 reads (32%) | called by muse, mutect2, varscan2
- ZNF681 | c.147G>A p.K49= | Silent (SNP) | VAF 19/530 reads (4%) | called by muse, mutect2
- AGBL4 | c.1267+1984G>T | Intron (SNP) | VAF 25/59 reads (42%) | called by muse, mutect2, varscan2
- AGO1 | c.*3068C>T | 3'UTR (SNP) | VAF 4/41 reads (10%) | called by muse, mutect2
- APAF1 | c.*2635G>T | 3'UTR (SNP) | VAF 13/59 reads (22%) | called by muse, mutect2, varscan2
- APH1B | c.*2419T>G | 3'UTR (SNP) | VAF 19/69 reads (28%) | called by muse, mutect2, varscan2
- ARC | c.*435G>A | 3'UTR (SNP) | VAF 11/17 reads (65%) | called by muse, mutect2, varscan2
- ATM | c.*3155G>A | 3'UTR (SNP) | VAF 31/107 reads (29%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122020995 C>G | 5'Flank (SNP) | VAF 33/73 reads (45%) | catalogued as COSV55849233, COSV55850852; called by muse, mutect2, varscan2
- BCL7A | chr12:122021509 A>G | 5'Flank (SNP) | VAF 16/40 reads (40%) | called by muse, varscan2
- BCL7A | c.*78G>A | 3'UTR (SNP) | VAF 153/287 reads (53%) | catalogued as rs918098606; called by muse, mutect2, varscan2
- BTG2 | c.*113_*114del | 3'UTR (DEL) | VAF 18/38 reads (47%) | called by mutect2, pindel, varscan2
- CAPN5 | c.-36+6013C>G | Intron (SNP) | VAF 4/37 reads (11%) | called by muse, mutect2, varscan2
- CFLAR | c.523+458_523+471del | Intron (DEL) | VAF 17/51 reads (33%) | called by mutect2, pindel, varscan2
- CIAO3 | c.823+10C>T | Intron (SNP) | VAF 15/23 reads (65%) | catalogued as rs773251858; called by muse, mutect2, varscan2
- CNPY1 | c.*1322T>A | 3'UTR (SNP) | VAF 22/56 reads (39%) | called by muse, mutect2, varscan2
- CXCL2 | c.-47G>A | 5'UTR (SNP) | VAF 9/22 reads (41%) | called by muse, mutect2, varscan2
- DTX1 | c.-127G>A | 5'UTR (SNP) | VAF 24/52 reads (46%) | catalogued as COSV57496634; called by muse, mutect2, varscan2
- ELAVL4 | c.-158C>A | 5'UTR (SNP) | VAF 9/13 reads (69%) | catalogued as rs896234352; called by muse, mutect2, varscan2
- EMC1 | c.*1498A>T | 3'UTR (SNP) | VAF 44/108 reads (41%) | called by muse, mutect2, varscan2
- ENPP1 | c.*1086T>C | 3'UTR (SNP) | VAF 4/56 reads (7%) | called by muse, mutect2
- EYS | c.862+52C>A | Intron (SNP) | VAF 7/17 reads (41%) | called by muse, mutect2, varscan2
- FAT2 | chr5:151504093 A>T | 3'Flank (SNP) | VAF 28/35 reads (80%) | called by muse, mutect2
- FERMT3 | c.-10A>G | 5'UTR (SNP) | VAF 70/100 reads (70%) | called by muse, varscan2
- GFOD1 | c.*5153T>C | 3'UTR (SNP) | VAF 28/57 reads (49%) | called by muse, mutect2, varscan2
- GNAI2 | c.119-556C>T | Intron (SNP) | VAF 14/28 reads (50%) | called by mutect2, varscan2
- HINFP | c.-10-591A>G | Intron (SNP) | VAF 4/11 reads (36%) | called by muse, varscan2
- IL23R | c.*554G>A | 3'UTR (SNP) | VAF 10/17 reads (59%) | called by muse, mutect2, varscan2
- INO80E | c.397-49C>T | Intron (SNP) | VAF 54/126 reads (43%) | called by muse, mutect2, varscan2
- INPP4B | chr4:142024486 ins T | 3'Flank (INS) | VAF 117/132 reads (89%) | called by mutect2, varscan2
- KRT20 | c.*181C>T | 3'UTR (SNP) | VAF 57/174 reads (33%) | called by muse, mutect2, varscan2
- LIMD2 | c.-50-34T>C | Intron (SNP) | VAF 9/21 reads (43%) | called by muse, mutect2, varscan2
- MAPKAPK2 | c.*20C>T | 3'UTR (SNP) | VAF 39/81 reads (48%) | catalogued as rs950592569; called by muse, mutect2, varscan2
- MAST4 | c.*1557T>C | 3'UTR (SNP) | VAF 30/105 reads (29%) | called by muse, mutect2, varscan2
- MIR4313 | chr15:75762126 C>A | 3'Flank (SNP) | VAF 6/21 reads (29%) | called by muse, mutect2, varscan2
- MMP13 | c.*12A>G | 3'UTR (SNP) | VAF 20/594 reads (3%) | called by muse, mutect2
- MPPED2 | c.*902C>T | 3'UTR (SNP) | VAF 31/80 reads (39%) | catalogued as rs561376698; called by muse, mutect2, varscan2
- NR1I2 | c.*1094C>T | 3'UTR (SNP) | VAF 26/56 reads (46%) | called by muse, mutect2, varscan2
- PDK4 | c.*1668dup | 3'UTR (INS) | VAF 35/63 reads (56%) | called by mutect2, varscan2
- PDLIM2 | chr8:22597952 C>A | 3'Flank (SNP) | VAF 7/10 reads (70%) | called by muse, mutect2, varscan2
- PELI1 | c.*1828T>A | 3'UTR (SNP) | VAF 23/46 reads (50%) | called by muse, varscan2
- PELI1 | c.*1653T>C | 3'UTR (SNP) | VAF 33/59 reads (56%) | called by muse, mutect2, varscan2
- PLA2G4F | c.*658G>T | 3'UTR (SNP) | VAF 22/86 reads (26%) | called by muse, mutect2, varscan2
- PLSCR5 | c.-226C>T | 5'UTR (SNP) | VAF 39/76 reads (51%) | called by muse, mutect2, varscan2
- POLR2K | c.*398G>T | 3'UTR (SNP) | VAF 16/30 reads (53%) | called by muse, mutect2, varscan2
- PPP1R15B | c.-332A>G | 5'UTR (SNP) | VAF 41/81 reads (51%) | called by muse, mutect2, varscan2
- PRC1 | chr15:90994640 del G | 5'Flank (DEL) | VAF 8/57 reads (14%) | called by mutect2, pindel, varscan2
- PRPF4 | c.*1214_*1217del | 3'UTR (DEL) | VAF 24/134 reads (18%) | called by mutect2, pindel, varscan2
- PTENP1 | n.1083G>A | RNA (SNP) | VAF 33/222 reads (15%) | catalogued as rs1193784471; called by muse, mutect2, varscan2
- RAB8B | c.*3904G>T | 3'UTR (SNP) | VAF 7/163 reads (4%) | called by muse, mutect2
- RCC1 | c.-162G>C | 5'UTR (SNP) | VAF 30/75 reads (40%) | catalogued as COSV100775641; called by muse, mutect2, varscan2
- REEP3 | c.*3923A>G | 3'UTR (SNP) | VAF 64/101 reads (63%) | called by muse, mutect2, varscan2
- RIT2 | c.-25T>G | 5'UTR (SNP) | VAF 34/74 reads (46%) | called by muse, mutect2, varscan2
- SCO1 | c.*7C>T | 3'UTR (SNP) | VAF 105/213 reads (49%) | called by muse, mutect2, varscan2
- SEMA3E | c.-84C>T | 5'UTR (SNP) | VAF 8/27 reads (30%) | catalogued as rs1404755766, COSV100317328; called by muse, mutect2, varscan2
- SOX3 | c.*532T>A | 3'UTR (SNP) | VAF 5/49 reads (10%) | called by muse, mutect2, varscan2
- STXBP4 | c.*524C>G | 3'UTR (SNP) | VAF 7/94 reads (7%) | called by muse, mutect2
- UACA | c.1169-247A>T | Intron (SNP) | VAF 53/191 reads (28%) | called by muse, mutect2, varscan2
- ZFHX4 | c.3847-66A>C | Intron (SNP) | VAF 26/63 reads (41%) | called by muse, mutect2, varscan2
- ZNF829 | c.*1424C>G | 3'UTR (SNP) | VAF 22/86 reads (26%) | called by muse, mutect2, varscan2
